Gene-level copy-number profile of tumor specimen TCGA-25-2398-01A from TCGA case TCGA-25-2398, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.9 years (26,267 days).
Specimen TCGA-25-2398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.153cbdd2-f7cd-4eff-8e91-20feba468aa1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2398-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71249504-14b7-437f-a1f0-8d2fb783c227

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 718; copy number 2: 6,611; copy number 3: 12,658; copy number 4: 18,008; copy number 5: 13,574; copy number 6: 4,734; copy number 7: 1,375; copy number 8: 1,003; copy number 9: 410; copy number 10: 24; copy number 11: 444; copy number 12: 1; copy number 13: 24; copy number 14: 169; copy number 18: 42; copy number 22: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-2398-01A-01D-0704-01): tumor purity 0.6, ploidy 4.21, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,132 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:233,614,106–235,452,443, 55 genes, copy number 14–18 (within-gene range 8–18): KCNK1, MIR4427, AL357972.1, AL663058.1, AL663058.2, AL713868.1, SLC35F3, RAC1P7, AL122008.3, AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE.
- chr1:243,488,233–243,851,079, 1 gene, copy number 22 (within-gene range 6–22): AKT3.
- chr1:243,624,666–244,641,177, 17 genes, copy number 22 (within-gene range 7–22): FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5.
- chr1:246,321,663–247,348,076, 44 genes, copy number 11: SMYD3-IT1, Y_RNA, AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1, ZNF695, ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1, AL627095.1, ZNF669, AL627095.2, C1orf229, FGFR3P6, ZNF124, AL390728.3, AL390728.2, AL390728.6, AL390728.4, MIR3916, RNA5SP82, AL390728.5, AL390728.1, VN1R17P, VN1R5, Y_RNA, ZNF496, AC104335.1.
- chr5:418,703–17,670,571, 325 genes, copy number 9–11 (broad region; genes not listed).
- chr5:38,937,920–44,066,731, 90 genes, copy number 11 (broad region; genes not listed).
- chr6:159,468,601–159,662,627, 1 gene, copy number 13 (within-gene range 8–13): AL078604.4.
- chr6:159,555,964–161,274,061, 39 genes, copy number 10–13: AL078604.3, AL078604.2, SOD2, HNRNPH1P1, RNU4ATAC18P, WTAP, SOD2-OT1, ACAT2, TCP1, SNORA20, SNORA29, MRPL18, PNLDC1, AL035691.1, MAS1, IGF2R, AIRN, CHP1P2, SLC22A1, AL645733.1, SLC22A2, AL162582.1, SLC22A3, AL591069.1, LPAL2, LPA, AL109933.2, AL109933.1, PLG, AL109933.5, AL109933.4, AL109933.3, AL391361.2, AL391361.1, AL139393.2, AL139393.1, MAP3K4-AS1, MAP3K4, AGPAT4.
- chr6:161,353,679–161,446,016, 2 genes, copy number 10–12: AL132982.1, AL138716.1.
- chr8:109,240,919–131,432,869, 263 genes, copy number 9–14 (broad region; genes not listed).
- chr10:56,595,963–56,596,031, 1 gene, copy number 13: AC025039.1.
- chr20:45,416,084–47,990,127, 95 genes, copy number 9 (broad region; genes not listed).
- chr22:29,191,697–31,388,837, 107 genes, copy number 9 (broad region; genes not listed).
- chr22:32,507,820–33,058,381, 1 gene, copy number 9 (within-gene range 5–9): SYN3.
- chr22:32,635,102–33,145,861, 7 genes, copy number 9: RNA5SP497, Z73495.1, TIMP3, Z83846.1, LINC01640, Z82198.1, Z82198.3.
- chr22:33,164,063–33,166,439, 1 gene, copy number 9: Z82198.2.
- chr22:37,686,414–39,279,897, 83 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 46. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
